Surgical pathology report (de-identified scan), TCGA case TCGA-24-1549, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1549-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

*** Converted Case * This report may not match the original report format**

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED
EPITHELIAL TYPE (ENDOMETRIOID AND PAPILLARY SEROUS)
- ADENOCARCINOMA EXTENSIVELY INVOLVES LYMPH VASCULAR
SPACES

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- CHRONIC INFLAMMATION WITH REACTIVE EPITHELIAL ATYPIA
- NO CARCINOMA IDENTIFIED

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED
EPITHELIAL TYPE (ENDOMETRIOID AND PAPILLARY SEROUS)
- EXTENSIVE OVARIAN ADHESIONS WITH FOCAL METASTATIC
ADENOCARCINOMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- PERITUBAL ADHESIONS WITH METASTATIC ADENOCARCINOMA

LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN 2 LYMPH NODES (0/2)

LYMPH NODES, RIGHT OBTURATOR, EXCISION

- NO CARCINOMA IDENTIFIED IN 2 LYMPH NODES (0/2)

LYMPH NODES, LEFT ILIAC, EXCISION

- NO CARCINOMA IDENTIFIED IN 3 LYMPH NODES (0/3)

LYMPH NODES, LEFT OBTURATOR, EXCISION

- NO CARCINOMA IDENTIFIED IN 4 LYMPH NODES (0/4)
- ENDOSALPINGIOSIS IS PRESENT IN 1 LYMPH NODE

LYMPH NODE, RIGHT PARA-AORTIC, EXCISION

- NO CARCINOMA IDENTIFIED IN 2 LYMPH NODES (0/2)

OMENTUM, OMENTECTOMY

- METASTATIC ADENOCARCINOMA, 0.9 CM IN GREATEST
DIMENSION

SOFT TISSUE, LEFT PELVIC SIDEWALL, BIOPSY

- FIBROADIPOSE TISSUE WITH FOCAL ENDOSALPINGIOSIS
- NO CARCINOMA IDENTIFIED

SOFT TISSUE, ANTERIOR CUL-DE-SAC, BIOPSY

- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

SOFT TISSUE, RIGHT PELVIC SIDEWALL, BIOPSY
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY
- FIBROADIPOSE TISSUE AND SMOOTH MUSCLE WITH NO
CARCINOMA IDENTIFIED

SOFT TISSUE, LEFT GUTTER, BIOPSY
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

SOFT TISSUE, RIGHT GUTTER, BIOPSY
- FIBROADIPOSE TISSUE WITH NO CARCINOMA IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my personal
examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

FS1: Ovary, right, salpingo-oophorectomy
- "Poorly differentiated adenocarcinoma, favor mullerian
origin,

Microscopic Description and Comment:

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Mixed epithelial type - papillary serous and endometrioid
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular
nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES involve the adjacent peritubal soft tissue.
9. Tumor DOES NOT invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is NOT
PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum
CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true
pelvis is 0.9 cm.
14. Metastatic involvement of the uterine serosa CANNOT BE
EVALUATED.
15. Metastatic involvement of the endometrium CANNOT BE
EVALUATED.
16. Regional lymph node metastases are ABSENT.
17. The total number of regional lymph nodes examined is 13.
18. The total number of metastatically-involved regional lymph
nodes is 0.
Extranodal extension by tumor is NOT APPLICABLE; no
nodal metastases are present
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is
classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3b	IIIB	Macroscopic peritoneal metastasis beyond true pelvis, with no implant greater than 2 cm in maximum dimension.

THE REGIONAL LYMPH NODES are classified as:
NO (Nodes are free of metastases)

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient is a [REDACTED] with history of total abdominal hysterectomy for benign disease in [REDACTED] and [REDACTED]. [REDACTED] is presenting with a right adnexal mass. Clinical diagnosis: Not provided. Operative procedure: Exploratory laparotomy; bilateral salpingo-oophorectomy; ovarian cancer staging.

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pick up and open right adnexa that measures 13.0 x 10.0 x 7.0 cm. Two cystic structures present, one of which has been intraoperatively opened during removal. Other cyst opened to show grossly suspicious solid and papillary structure lining cyst wall. Portion of this and underlying solid area frozen. Remainder for permanents," by [REDACTED]

Specimen(s) Received:

A: FS1-OVARY, RIGHT
B: X1-OVARY, RIGHT
C: LEFT ADNEXA
D: RIGHT EXTERNAL ILIAC LYMPH NODE
E: RIGHT OBTURATOR LYMPH NODE
F: LEFT EXTERNAL ILIAC LYMPH NODE
G: LEFT OBTURATOR
H: LEFT PELVIC SIDE WALL
I: ANTERIOR CUL-DE-SAC
J: RIGHT PELVIC SIDE WALL
K: POSTERIOR CUL-DE-SAC
L: LEFT GUTTER
M: RIGHT GUTTER
N: OMENTUM
O: RIGHT PARA AORTIC LYMPH NODE

Gross Description:

The specimens are received in fifteen containers of formalin, each labelled with the patient's name. The first container is labeled "FS." It contains a fragment of tan-white, soft tissue measuring 2.0 x 1.1 x 0.2 cm. [REDACTED]

The second container is labeled "right adnexa, X1." It contains a fragment of tan-white/light blue soft tissue measuring 13.0 x 10.0 x 7.0 cm. Two previously opened cysts are present measuring 8.0 and 5.0 cm in diameter, respectively. A tan-white tubular structure measuring 6.0 cm in length and 0.8 cm in diameter is attached and opens into the smaller cyst. There are papillary and solid growths on both cysts walls. The area of solid growth brings these two cysts together. The solid mass is not well defined measuring 4.9 cm in greatest dimension. The cut surfaces are tan-white, soft, showing areas of hemorrhage and necrosis. Labeled X1 to X6 - tumor (X3, X4 and X5, X6 are in continuation); X7, X8 - fallopian tube. [REDACTED]

The third container is labeled "left adnexa." It contains a fragment of tan-yellow, soft tissue measuring 5.8 x 3.8 x 1.8 cm. An ovary is covered by fibrofatty tissue and measures 2.3 x 1.4 x 1.4 cm in greatest dimensions. The surface of the ovary is smooth and cut surface shows no involvement by tumor. The fallopian tube measures 6.5 cm in length and 0.5 cm in average diameter. Sections show luminal space lined by light yellow epithelial tissue. The fallopian tube is not involved by tumor either.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Labeled A1 - left ovary; A2 - left fallopian tube. [REDACTED]

The fourth container is labeled "right external iliac lymph node." It contains a fragment of yellow, fibrofatty tissue, measuring 3.8 x 2.8 x 2.0 cm. Two lymph nodes measuring 0.9 and 2.1 cm in greatest dimension are identified. The lymph nodes are bisected and half of each are submitted. [REDACTED]

The fifth container is labeled "right obturator lymph node." It contains a fragment of yellow, fibrofatty tissue measuring 5.7 x 3.0 x 1.0 cm. Two lymph nodes measure 3.4 and 1.6 cm in greatest dimension are identified. The lymph nodes are bisected and half of each are submitted. [REDACTED]

The sixth container is labeled "left iliac lymph node." It contains a fragment of yellow, fibrofatty tissue, measuring 4.6 x 4.0 x 1.5 cm. Three lymph nodes ranging from 0.4 to 2.1 cm in greatest dimension are bisected. The lymph nodes are bisected and half of each are submitted. [REDACTED]

The seventh container is labeled "left obturator lymph node." It contains a fragment of yellow fibrofatty tissue measuring 5.0 x 2.0 x 0.8 cm. Two lymph nodes measuring 1.1 and 4.5 cm in greatest dimension are bisected. The lymph nodes are bisected and half of each are submitted. [REDACTED]

The eighth container is labeled "left pelvic sidewall." It contains a fragment of tan-white to black, soft tissue, measuring 1.5 x 1.1 x 0.4 cm. [REDACTED]

The ninth container is labeled "anterior cul-de-sac." It contains a fragment of tan-white, soft, tissue, measuring 0.9 x 0.5 x 0.3 cm. [REDACTED]

The tenth container is labeled "right pelvic sidewall." It contains a fragment of tan, soft, tissue, measuring 1.2 x 0.6 x 0.3 cm. [REDACTED]

The eleventh container is labeled "posterior cul-de-sac." It contains a fragment of tan to black, soft, tissue, measuring 0.4 x 0.3 x 0.3 cm. [REDACTED]

The twelfth container is labeled "left gutter." It contains a fragment of tan-white to light blue, soft tissue, measuring 0.9 x 0.5 x 0.4 cm. [REDACTED]

The thirteenth container is labeled "right gutter." It contains a fragment of tan, soft tissue, measuring 1.1 x 0.4 x 0.4 cm. [REDACTED]

The fourteenth container is labeled "omentum." It contains a fragment of yellow, fatty tissue, measuring 25.0 x 15.0 x 1.2 cm in greatest dimension. Serial sections show an area of fibrosis measuring 0.9 x 0.9 x 0.7 cm. A cyst is found in this area of fibrosis showing hemorrhage and myxoid degeneration measuring 0.6 cm in diameter. The rest of the omentum is grossly unremarkable. [REDACTED]

The fifteenth container is labeled "right para-aortic lymph node." It contains two fragments of tan-yellow-black, fibrofatty tissue measuring 2.5 x 1.5 x 0.9 cm in aggregate. One lymph node measuring 1.0 cm in greatest dimension is dissected. The lymph node is bisected and half of it is submitted along with a hematoma measuring 0.6 cm in greatest dimension. [REDACTED]

Source: NCI Genomic Data Commons file e89ffbc3-e7ce-480c-a5e4-5cc18c79b89f (TCGA-24-1549.6431416B-D089-442D-9DB8-32118EED41DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).